CPTAC case 01BR009 — Breast (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Breast.
https://portal.gdc.cancer.gov/cases/16614d46-172b-479c-992b-e80a8e9a2c59

Demographics
Race: black or african american.

Biospecimens (3 samples)
- Samples CPT008752, CPT008930 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample CPT009156: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
